Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3T3, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3T3-01A (Primary Tumor).

[page 1 of 2]
Pathology
Port

DOB:

Sex

Physician:

Accession:

Collected:

Received:

Case type: Surgical Case

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) RIGHT INFERIOR PARATHYROID:

Parathyroid tissue identified.

(B) TOTAL THYROIDECTOMY AND RIGHT INFERIOR PARATHYROID:

PAPILLARY CARCINOMA OF THE THYROID (3.5 CM) AND THE TUMOR IS CONFINED TO THE THYROID GLAND.
MARGINS OF RESECTION ARE FREE OF TUMOR.

Thyroid adenoma.

Entire report and diagnosis completed by:

GROSS DESCRIPTION

(A) TISSUE RIGHT INFERIOR PARATHYROID - A red-brown soft tissue fragment (0.4 x 0.3 x 0.3 cm). The specimen is bisected and entirely submitted for frozen section in cassette A.

*FS/DX: PARATHYROID TISSUE CANNOT RULE OUT ADENOMA.

(B) TOTAL THYROIDECTOMY AND RIGHT INFERIOR PARATHYROID - A product of total thyroidectomy and an attached right nodule. The nodule on the right inferior aspect of the thyroid lobe measures 1.2 x 0.5 x 0.3 cm. Submitted entirely under B1. The right thyroid lobe measures 4.0 x 2.0 x 1.4 and appear grossly unremarkable. The left thyroid lobe measures 4.0 x 4.0 x 2.5 cm with ill-defined nodule which is soft. The left thyroid nodule measures 3.5 x 3.5 cm and is friable cystic and fibrotic. It is well circumscribed and does not involve the surgical margins. Specimen occupies the entire lobe except for approximately 0.5 cm of normal appearing thyroid tissue on superior aspect. Specimen is submitted under B2 to B5. The right thyroid lobe from superior to inferior; B6, B7, represent section from the isthmus and the left thyroid tumor from superior to inferior under B8-B17.

CLINICAL HISTORY

None given.

SNOMED CODES

T-B6000 T-B7000 M-80503 M-Y3410

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

Released by:

4-3-12
RO

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,

DOB:
Physician.

Sex: -

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

ADDENDUM

DIAGNOSIS

(A) RIGHT INFERIOR PARATHYROID:

Parathyroid tissue identified.

(B) TOTAL THYROIDECTOMY AND RIGHT INFERIOR PARATHYROID:

PAPILLARY CARCINOMA OF THE THYROID (3.5 CM) AND THE TUMOR IS CONFINED TO THE THYROID GLAND,
MARGINS OF RESECTION ARE FREE OF TUMOR.

Parathyroid adenoma.

Entire report and diagnosis completed by

Released by:

Surgical Pathology Report		Page 2 of 2
File under: Pathology		

Source: NCI Genomic Data Commons file a7d83797-37e5-4331-b5bd-8426f5c17c0d (TCGA-EL-A3T3.B2D489F2-AD1C-4D77-A077-E90BDB21546A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).